CCDI case PBBVVV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/6683d711-645d-401e-bedc-a0eb4bc92e70

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Myxopapillary ependymoma: ICD-O-3 morphology code: 9394/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 9.7 years (3,549 days).

Biospecimens (3 samples)
- Sample 0DIPKO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIPKY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DIPLO: Tissue type: Tumor; Specimen type: Solid Tissue.
